Somatic mutation profile of tumor specimen TCGA-CZ-4864-01A (aliquot TCGA-CZ-4864-01A-01D-1501-10) from TCGA case TCGA-CZ-4864, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CZ-4864-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b24f6ec-b38b-400c-88d6-477f09936059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-4864-11A (Solid Tissue Normal), aliquot TCGA-CZ-4864-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4633a8cb-d950-4236-9125-a0bc635f730a

The open-access MAF lists 74 somatic variants for this specimen: 57 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Frame Shift Del 4, Splice Site 3, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779580, CM1412664, COSV100483883; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.409G>C p.D137H (on ENST00000506720 / NM_001322402.2; = p.D69H on NM_015236.6) | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV101546995, COSV101547427; called by muse, mutect2, varscan2
- AHCTF1 | c.2249+1G>T p.X750_splice (on ENST00000366508; = p.X724_splice on NM_015446.5) | Splice Site (SNP) | VAF 142/444 reads (32%) | catalogued as COSV100404562; called by muse, mutect2, varscan2
- BAP1 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); catalogued as COSV99964596; called by muse, mutect2, varscan2
- BCAS3 | c.2380C>G p.P794A (on ENST00000390652 / NM_001353144.2; = p.P779A on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV101177360; called by muse, mutect2, varscan2
- CATSPERD | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as rs1425679591, COSV100638792; called by mutect2, varscan2
- CBX2 | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV99491058; called by muse, mutect2, varscan2
- COL6A2 | c.1582G>C p.G528R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100154463; called by muse, mutect2
- CSF2RB | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.049); catalogued as COSV99454607; called by muse, mutect2, varscan2
- CUL4B | c.2079G>T p.M693I | Missense Mutation (SNP) | VAF 176/280 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV100341295; called by muse, mutect2, varscan2
- DDX39A | c.546G>C p.R182S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99660563; called by muse, mutect2, varscan2
- DST | c.1261G>A p.G421R (on ENST00000361203 / NM_001374722.1; = p.G95R on NM_001723.6) | Missense Mutation (SNP) | VAF 125/407 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760819; called by muse, mutect2, varscan2
- DYNC2H1 | c.11276A>G p.Q3759R | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100519974; called by muse, varscan2
- ETFDH | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 174/637 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100310156; called by muse, mutect2, varscan2
- GLYCTK | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99980987; called by muse, mutect2, varscan2
- GPT | c.1370T>C p.F457S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99477900; called by muse, mutect2
- HK3 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761890560, COSV52838561; called by muse, mutect2, varscan2
- HMGCS1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 135/384 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV100285104, COSV57291816; called by muse, mutect2, varscan2
- IFT57 | c.44A>C p.D15A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99198290; called by muse, mutect2
- IL33 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 167/627 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101197924; called by muse, mutect2, varscan2
- KCNT1 | c.2218T>C p.Y740H (on ENST00000488444; = p.Y759H on NM_020822.3) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99706955; called by muse, mutect2, varscan2
- MAB21L3 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV101046541; called by muse, mutect2
- MAP1A | c.2084G>C p.S695T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100289380; called by muse, mutect2, varscan2
- MINK1 | c.3959A>C p.Y1320S | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99545443; called by muse, mutect2, varscan2
- MKKS | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV100726333, COSV61399379; called by muse, mutect2, varscan2
- MTUS2 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV70916931; called by muse, mutect2, varscan2
- NUSAP1 | c.47A>C p.D16A | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99531198; called by muse, varscan2
- OR4C11 | c.193T>G p.S65A | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100155068, COSV100155576; called by muse, mutect2, varscan2
- OR6N1 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100625324; called by muse, mutect2, varscan2
- PDCD5 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 103/407 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99694823; called by muse, mutect2, varscan2
- PRMT7 | c.746+1G>A p.X249_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as rs760575619, COSV100267320; called by muse, varscan2
- PRSS55 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100153902; called by muse, mutect2
- RGS3 | c.1447C>T p.P483S (on ENST00000350696 / NM_001282923.2; = p.P371S on NM_017790.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100466067; called by muse, mutect2, varscan2
- RTN3 | c.1753G>C p.V585L (on ENST00000377819 / NM_001265589.2; = p.V566L on NM_201428.3) | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV100380411; called by muse, mutect2, varscan2
- SBF2 | c.1805T>C p.I602T | Missense Mutation (SNP) | VAF 130/422 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV99816085; called by muse, mutect2, varscan2
- SH3TC2 | c.3295C>A p.R1099S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100102493; called by muse, mutect2, varscan2
- SMC1B | c.1568G>T p.C523F | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663574; called by muse, mutect2, varscan2
- SNED1 | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs370559891; called by muse, mutect2, varscan2
- SNX19 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV99773707; called by muse, mutect2, varscan2
- STAP2 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV101654927; called by muse, mutect2, varscan2
- STK3 | c.1136T>C p.M379T | Missense Mutation (SNP) | VAF 140/573 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV101372677; called by muse, mutect2
- SUN5 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs767217191, COSV99401408; called by muse, mutect2, varscan2
- TAOK3 | c.1288C>G p.R430G | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV101183842; called by muse, mutect2
- TARS1 | c.1699T>A p.L567M | Missense Mutation (SNP) | VAF 97/375 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV54312464, COSV99466570; called by muse, mutect2, varscan2
- TBX21 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99456375; called by muse, mutect2, varscan2
- THBS1 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV99528530; called by muse, mutect2, varscan2
- TMEM130 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100229061; called by muse, mutect2, varscan2
- UBAC2 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 399/1311 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100854448; called by muse, mutect2, varscan2
- UBQLN4 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100849127, COSV64145962; called by muse, mutect2, varscan2
- UNC13C | c.5650G>C p.D1884H | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV52844038, COSV99523934; called by muse, mutect2, varscan2
- USP5 | c.977C>A p.T326K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99979134; called by muse, mutect2, varscan2
- ARHGAP25 | c.216_217del p.Q73Afs*8 (on ENST00000409202 / NM_001007231.3; = p.Q66Afs*8 on NM_014882.3) | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by pindel, varscan2
- CCAR1 | c.798_816del p.Q266Hfs*14 | Frame Shift Del (DEL) | VAF 65/305 reads (21%) | called by mutect2, pindel*, varscan2*
- IDH3A | c.715-12_717del p.X239_splice | Splice Site (DEL) | VAF 216/976 reads (22%) | called by mutect2, pindel, varscan2
- SCNN1B | c.457del p.I153Lfs*22 | Frame Shift Del (DEL) | VAF 69/249 reads (28%) | called by mutect2, pindel, varscan2
- SF3B3 | c.1100_1101dup p.D368Mfs*46 | Frame Shift Ins (INS) | VAF 94/332 reads (28%) | called by mutect2, pindel, varscan2
- TPD52L2 | c.233del p.K78Rfs*12 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- DYRK1A | c.1335G>A p.T445= | Silent (SNP) | VAF 65/186 reads (35%) | catalogued as rs376512809; called by muse, mutect2, varscan2
- EVPL | c.2427C>T p.H809= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV101646202; called by muse, mutect2, varscan2
- EXT2 | c.1575T>A p.P525= (on ENST00000343631; = p.P558= on NM_000401.3) | Silent (SNP) | VAF 147/438 reads (34%) | catalogued as COSV100640707; called by muse, mutect2, varscan2
- IL20RA | c.951G>C p.S317= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV100360262; called by muse, mutect2
- INPP5F | c.891A>T p.G297= | Silent (SNP) | VAF 143/493 reads (29%) | catalogued as COSV100740445; called by muse, mutect2, varscan2
- KLK6 | c.399C>T p.A133= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100037884; called by muse, mutect2, varscan2
- KRTAP10-11 | c.33C>T p.S11= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs587690905, COSV58178969; called by muse, mutect2, varscan2
- MSRA | c.561C>G p.G187= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100413828; called by muse, mutect2, varscan2
- NSD1 | c.1641C>T p.A547= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV61774632; called by muse, mutect2, varscan2
- OR52E4 | c.351G>A p.L117= | Silent (SNP) | VAF 59/173 reads (34%) | catalogued as COSV100389412; called by muse, mutect2, varscan2
- PCDHGA3 | c.1110C>T p.D370= | Silent (SNP) | VAF 73/353 reads (21%) | catalogued as rs774990344, COSV53920308; called by muse, mutect2, varscan2
- PLXNA1 | c.4311A>T p.A1437= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV99304307; called by muse, mutect2, varscan2
- PRICKLE4 | c.426A>T p.A142= (on ENST00000359201; = p.A182= on NM_013397.6) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100138940; called by muse, mutect2, varscan2
- SLC22A8 | c.1293C>G p.L431= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV100268151; called by muse, mutect2, varscan2
- STMN4 | c.198C>T p.V66= (on ENST00000265770 / NM_001283054.2; = p.V93= on NM_030795.4) | Silent (SNP) | VAF 73/244 reads (30%) | catalogued as rs1446314657, COSV99741205; called by muse, mutect2, varscan2
- MICAL3 | c.2605+95T>G | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99263162; called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4301G>T | Intron (SNP) | VAF 35/123 reads (28%) | catalogued as COSV100327781; called by muse, mutect2, varscan2
